Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A43U, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A43U-01A (Primary Tumor).

[page 1 of 4]
Gender: Male

DOB:

Race: White

Report Date:

1c5-0-3
carcinoma, urothelial, nos 812013
CQCF Site: bladder, wall, lateral C67.2
Path: bladder, nos C67.9

Pathology Report:

lw
9/29/12

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Right pelvic lymph nodes; dissection:

- Six of twenty three lymph nodes with metastatic urothelial carcinoma (6/23).
- Largest nodal tumor focus measures 3 mm, with extranodal tumor extension.

B. Left pelvic lymph nodes; dissection:

- One of ten lymph nodes with metastatic urothelial carcinoma (1/10).
- Largest nodal tumor focus measures 1.4 cm, with extranodal tumor extension.

C. Urinary bladder, prostate, seminal vesicles and vasa deferentia; cystoprostatectomy:

- Invasive high grade urothelial carcinoma, see pathologic parameters.
- Tumor invades thru the bladder wall and into the perivesical fat, periprostatic tissue and focally the prostate.
- Tumor involves the right periprostatic soft tissue margin.
- One perivesical lymph node, no tumor (0/1).

D. Left distal ureter; resection:

- Segment of ureteral wall, no tumor.

E. Distal right ureter; resection

- Segment of ureter, no tumor.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Invasive urothelial carcinoma.
2. Grade of tumor: High grade
3. Depth of invasion: Extravesicular soft tissue, periprostatic tissue and prostate.
4. Tumor distribution: Solitary, 3.5 cm, mass involves bladder posterior, left

[page 2 of 4]
and right lateral, anterior and trigone walls and prostate.

5. Ureteral margins: Negative for tumor.

6. Distal urethral margin: Negative for tumor.

7. Soft tissue margin or serosa: Positive for tumor (at right periprostatic soft tissue margin, 5 mm [slide C23]).

8. Lymph nodes: Positive for tumor (7/34).

9. pTNM: pT4a,N2,MX, R1.

this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

xx

☐ MD

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, ☐ M.D.

Electronically Signed Out by ☐ MD

Clinical History:

This is a year-old man with history of urothelial carcinoma, high grade invasive into the prostatic stroma and lamina propria. He now undergoes cystoprostatectomy and lymph node dissection.

Specimens Received:

A: Right pelvic lymph nodes

B: Left pelvic lymph nodes

C: Bladder, prostate, seminal vesicles & vas deferens

D: Left distal ureter

E: Distal right ureter

Gross Description:

The specimens are received in five containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "1. Right pelvic lymph node". Received fresh and placed in formalin is a 7.5 x 6 x 2.5 cm aggregate of yellow-brown lobular tissue from which multiple lymph node candidates measuring 0.3-1.1 cm are identified.

A1-A2: 5 candidate lymph nodes

A3-A4: 6 candidate lymph nodes

A5: One candidate lymph node, bisected

A6: One candidate lymph node, sectioned

B. The second container is additionally identified as, "2. Left pelvic lymph

[page 3 of 4]
nodes". Received fresh and placed in formalin is a 7 x 4.5 x 3 cm aggregate of yellow-brown lobular tissue from which multiple lymph node candidates measuring 0.3-3.5 cm are identified.

B1: 4 candidate lymph nodes

B2: 5 candidate lymph nodes

B3: 3 candidate lymph nodes

B4: One candidate lymph node, bisected

B5-B8: One candidate lymph node, sectioned

B9-B11: One candidate lymph node, grossly involved by tumor, representative sections

C. The third container is additionally identified as, "3. Bladder, prostate, seminal vesicles, vas deferens". Received fresh and placed in formalin is a 17.5 x 9 x 6 cm cystoprostatectomy specimen consisting of a 0.2 x 6 x 4.5 cm bladder with attached mesenteric fat and an approximately 5 x 4 x 3 cm prostate. The right seminal vesicles measure 4.5 x 3 x 1 cm and right vas deferens measures 8 x 0.6 cm. The left seminal vesicles measures 4 x 3.1 x 1.3 cm and left vas deferens measures 2.5 x 0.6 cm. The right ureteral stump measures 3 x 0.6 cm, the left measures 2.2 x 0.6 cm, and both demonstrate intact, patent lumens.

The right half of the prostate and bladder is inked blue and the left half is inked black. The outer surface of the bladder is inked black. The bladder and prostate are opened anteriorly along the urethra. The capsule is absent and the apex of the prostate is disrupted. Sectioning demonstrates ill-defined broad areas of firm, yellow-tan indurations throughout the prostate parenchyma focally extending to ink. The seminal vesicles demonstrate cystic cut surface with gold-brown thick secretion. The left seminal vesicle is focally grossly involved by the lesion.

The opened bladder reveals a red-brown lesion with shaggy and ulcerated surface involving the entire posterior wall extending to the left and right lateral walls as well as the inferior anterior wall. The lesion measures 3.5 x 1.5 cm. On cut section, the bladder demonstrates firm yellow-tan cut surface grossly consistent with tumor involvement/possible fibrosis with maximal thickness of 2.2 cm. The lesion extends through the lamina propria into the perivesicular fat to within 0.2 cm of the ink. On one section it surrounds the right ureter. The surrounding bladder mucosa is edematous, wrinkled, tan-brown with wall thickness of 1.3 cm. Bilateral ureteral orifices, adjacent to the trigone, are identified and probe patent. Received separately in the same container is a 3 x 3 x 1 cm aggregate of yellow lobular adipose tissue from which one candidate lymph node measuring 0.2 cm identified.

Representative sections are submitted as follows:

C1: Distal prostatic urethral margin (apex)

C2: Right ureter resection margin

[page 4 of 4]
C3: Left ureter resection margin
C4: Prostatic apical margin
C5-C6: Lesion, left lateral wall, closest extension to ink
C7: Lesion, anterior wall, closest extension to ink
C8-C10: Lesion, posterior wall,
C11: Lesion, trigone
C12: Lesion, right lateral wall
C13: Lesion, surrounding right ureter
C14: Uninvolved dome
C15-C19: Left prostate, apex to base
C20: Left seminal vesicle and vas deferens
C21-C25: Right prostate, apex to base
C26-C27: Right seminal vesicle and vas deferens
C28: One candidate lymph node

D. The fourth container is additionally identified as, "4. Distal left ureter". Received fresh and placed in formalin is a soft and rubbery, tan-pink, and oriented, 1.0 x 0.4 x 0.2 cm tissue grossly consistent with mucosa with minimal attached adipose tissue. A lumen is not identified. The specimen is submitted in toto as E1

E. The fifth container is additionally identified as, "5. Distal right ureter, stitch on non-margin side". Received fresh and placed in formalin is a soft and rubbery, 1.2 x 0.9 x 0.6 cm tissue containing a segment of ureter with wall thickness of 0.1 cm and a patent lumen of 0.2 cm. B. margins side is trimmed and submitted as E1.

xx

[], M.D.

Source: NCI Genomic Data Commons file 72a2bed1-20fd-4fd3-8367-f029decc2d1a (TCGA-FD-A43U.FB7CF869-AA10-4C3E-9BDA-5686130DB4C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).